Gene-level copy-number profile of tumor specimen C3L-06642-01 from CPTAC case C3L-06642, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 71.3 years (26,049 days).
Specimen C3L-06642-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 54ed43f3-f6d5-4cdb-8ca2-04b5ec24b4c1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-06642-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/ce76f44b-a5ce-4a04-918c-c6c5b87b000a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 162; copy number 1: 15,189; copy number 2: 40,040; copy number 3: 1,728; copy number 4: 530; copy number 5: 754.

Homozygous deletions (total copy number 0; autosomes only): 162 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:156,011,530–156,254,950, 2 genes: LINC01876, HEBP2P1.
- chr9:9,442,060–9,803,784, 2 genes (within-gene range 0–1): RN7SL5P, AL513422.1.
- chr9:21,695,176–23,682,662, 26 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2.
- chr9:23,955,760–26,118,408, 9 genes: AL365204.3, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr14:21,841,240–22,552,156, 120 genes (within-gene range 0–1) (broad region; genes not listed).
- chr20:15,021,553–15,280,873, 3 genes (within-gene range 0–2): RNU6-1159P, RNU6-115P, RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 754 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:169,483,671–169,484,080, 1 gene, copy number 5 (within-gene range 4–5): RPL22P1.
- chr3:175,938,929–198,123,232, 472 genes, copy number 5 (broad region; genes not listed).
- chr5:2,712,591–21,779,522, 281 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,180. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
